Somatic mutation profile of tumor specimen TCGA-13-1487-01A (aliquot TCGA-13-1487-01A-01D-0472-01) from TCGA case TCGA-13-1487, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GX; Age at diagnosis: 74.4 years (27,176 days).
Specimen TCGA-13-1487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0339267-fb47-4040-9110-7754b911014d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1487-10A (Blood Derived Normal), aliquot TCGA-13-1487-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a32d5e9a-3d6c-41ae-ac49-b4023362876c

The open-access MAF lists 56 somatic variants for this specimen: 37 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Splice Site 2, RNA 2, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.710T>A p.M237K | Missense Mutation (SNP) | VAF 444/520 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765848205, COSV52682586, COSV53017093, COSV53037559, COSV53037741; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.1593T>G p.H531Q | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57079172; called by muse, mutect2, varscan2
- ALDOC | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376690171; called by muse, mutect2, varscan2
- ASH2L | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 35/955 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs770141592; called by muse, mutect2
- CARD17 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100995176, COSV65215715; called by muse, mutect2, varscan2
- CCNA2 | c.484A>C p.I162L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52659670; called by muse, mutect2, varscan2
- CCSER2 | c.608T>C p.L203S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56512940; called by muse, mutect2, varscan2
- CDH9 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1490543922, COSV50470115; called by muse, mutect2, varscan2
- CST3 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 20/89 reads (22%) | catalogued as COSV65362363; called by muse, mutect2, varscan2
- DYNC1H1 | c.13912C>T p.R4638W | Missense Mutation (SNP) | VAF 123/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200224597, COSV64142862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L3 | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59468445; called by muse, mutect2, varscan2
- EYA1 | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 106/412 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV58174519; called by muse, mutect2, varscan2
- ITPR3 | c.2729-2A>G p.X910_splice | Splice Site (SNP) | VAF 36/117 reads (31%) | catalogued as COSV65415123; called by muse, mutect2, varscan2
- JUP | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 74/109 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60279934; called by muse, mutect2, varscan2
- KRT13 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781460268, COSV55841572; called by muse, mutect2, varscan2
- MED26 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs771432171, COSV54663238; called by muse, mutect2, varscan2
- MMP19 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV100491281; called by muse, mutect2, varscan2
- NR1D1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs373443634, COSV52840970; called by mutect2, varscan2
- PEAR1 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as rs753945173, COSV52770985; called by muse, mutect2, varscan2
- PRKCI | c.1008T>G p.N336K | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV55516929, COSV55522835; called by muse, mutect2
- RORC | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs202038919, COSV59095905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGIP1 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as rs1359709055, COSV52766291; called by muse, mutect2, varscan2
- SLC12A5 | c.2207G>A p.G736D (on ENST00000454036 / NM_001134771.2; = p.G713D on NM_020708.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1363482191, COSV54802328; called by muse, mutect2, varscan2
- STAC | c.765C>T p.S255= | Splice Region (SNP) | VAF 46/152 reads (30%) | catalogued as rs377372947; called by muse, mutect2, varscan2
- SYNE1 | c.2760G>C p.K920N (on ENST00000367255 / NM_182961.4; = p.K927N on NM_033071.3) | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as rs770726839, COSV55109657; called by muse, mutect2, varscan2
- TRAPPC12 | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60852045; called by muse, mutect2, varscan2
- TSHZ1 | c.754A>T p.S252C (on ENST00000580243 / NM_001308210.2; = p.S207C on NM_005786.6) | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59017461; called by muse, mutect2, varscan2
- WWC1 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs139653620, COSV99514164; called by muse, mutect2, varscan2
- ZNF335 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs913937354, COSV59817994, COSV59820410; called by muse, mutect2, varscan2
- ZNF713 | c.163C>A p.L55I (on ENST00000633730 / NM_001366796.2; = p.L68I on NM_182633.3) | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1256093146, COSV68888405; called by muse, mutect2, varscan2
- ZNF773 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 77/437 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1238841318, COSV56590544; called by muse, mutect2, varscan2
- ZNF98 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1022721934; called by mutect2, varscan2
- ARL5A | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCDHGB7 | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.158); called by muse, mutect2
- PRSS53 | c.1645C>A p.Q549K | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRK | c.2142_2145del p.T715Lfs*6 | Frame Shift Del (DEL) | VAF 49/159 reads (31%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.315); called by muse, mutect2
- ANO3 | c.2946G>A p.*982= | Silent (SNP) | VAF 65/201 reads (32%) | catalogued as rs759722183, COSV56809472; called by muse, mutect2, varscan2
- COL17A1 | c.151C>A p.R51= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs371548263, COSV62229547; called by muse, mutect2, varscan2
- COL4A4 | c.1836A>G p.K612= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV61636876; called by muse, mutect2, varscan2
- FBXL16 | c.678G>C p.S226= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1467353885, COSV100178914, COSV60964348, COSV60965613; called by muse, mutect2, varscan2
- IGKV2D-30 | c.102C>T p.T34= | Silent (SNP) | VAF 33/211 reads (16%) | catalogued as rs759761805; called by muse, mutect2, varscan2
- IGKV5-2 | c.219T>C p.T73= | Silent (SNP) | VAF 82/340 reads (24%) | called by muse, mutect2
- INSM1 | c.1395C>G p.A465= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV59605395; called by muse, mutect2, varscan2
- METTL2A | c.1134C>T p.S378= | Silent (SNP) | VAF 287/664 reads (43%) | catalogued as COSV100274332; called by muse, mutect2, varscan2
- MKI67 | c.2659C>T p.L887= | Silent (SNP) | VAF 247/447 reads (55%) | catalogued as rs1387493462, COSV64077115; called by muse, mutect2, varscan2
- MLIP | c.339A>C p.A113= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as COSV51437741; called by muse, mutect2, varscan2
- MTO1 | c.1353C>A p.I451= (on ENST00000370300 / NM_133645.3; = p.I426= on NM_012123.4) | Silent (SNP) | VAF 94/343 reads (27%) | catalogued as COSV64775070, COSV64775147; called by muse, mutect2, varscan2
- NLRP11 | c.2253G>C p.L751= | Silent (SNP) | VAF 103/277 reads (37%) | catalogued as COSV64088874; called by muse, mutect2, varscan2
- NOL4 | c.1434A>G p.R478= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV52362971; called by muse, mutect2, varscan2
- PARP8 | c.2268C>T p.D756= | Silent (SNP) | VAF 51/192 reads (27%) | catalogued as rs201764927, COSV55867195; called by muse, mutect2, varscan2
- SERPINB13 | c.423C>T p.A141= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs150453343; called by muse, mutect2, varscan2
- SLC5A10 | c.588C>T p.D196= | Silent (SNP) | VAF 77/89 reads (87%) | catalogued as rs200235814; called by muse, mutect2, varscan2
- AC245047.1 | n.1G>C | RNA (SNP) | VAF 111/151 reads (74%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1504T>C | RNA (SNP) | VAF 52/148 reads (35%) | called by muse, mutect2, varscan2
- VGLL4 | c.64+31706C>A | Intron (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
